Gene-level copy-number profile of tumor specimen TCGA-GS-A9TZ-01A from TCGA case TCGA-GS-A9TZ, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mediastinal (thymic) large B-cell lymphoma; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 51.2 years (18,691 days).
Specimen TCGA-GS-A9TZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.d20cb7e6-53e5-40c5-87e7-f81a530b21a9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GS-A9TZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a32bc4a4-6f62-4ca8-8295-d62f79bb858f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 208; copy number 2: 1,243; copy number 3: 9,185; copy number 4: 32,785; copy number 5: 10,110; copy number 6: 4,643; copy number 7: 1,626; copy number 9: 17; copy number 13: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GS-A9TZ-01A-11D-A38W-01): tumor purity 0.39, ploidy 4.32, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:128,150,116–128,150,188, 1 gene, copy number 13: MIR1208.
- chr11:119,206,298–119,526,664, 17 genes, copy number 9 (within-gene range 4–9): CBL, RNU6-262P, MCAM, MIR6756, AP002956.1, RNF26, AP003396.1, C1QTNF5, MFRP, USP2, USP2-AS1, AP003396.3, AP003396.2, AP003396.4, THY1, THY1-AS1, DUXAP5.

Autosomal genes at a single copy (total copy number 1): 208. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
